Somatic mutation profile of tumor specimen TCGA-BT-A42B-01A (aliquot TCGA-BT-A42B-01A-32D-A23M-08) from TCGA case TCGA-BT-A42B, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 59.7 years (21,788 days).
Specimen TCGA-BT-A42B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5367f03d-d8c8-4cc3-a15b-0761c3db6831.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BT-A42B-10A (Blood Derived Normal), aliquot TCGA-BT-A42B-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/997d91a6-0299-470a-a1ff-a60a6ac9c39f

The open-access MAF lists 71 somatic variants for this specimen: 48 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 21, Nonsense Mutation 7, Frame Shift Del 2, Intron 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 43/86 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.4156A>G p.M1386V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV60683132; called by muse, mutect2, varscan2
- ADAM11 | c.1882G>A p.G628S | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.057); catalogued as COSV52345337; called by muse, mutect2, varscan2
- ANKRD36B | c.807C>G p.D269E | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754904396; called by muse, mutect2, varscan2
- AQP5 | c.40G>A p.V14M | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as rs776651494, COSV52229705; called by muse, mutect2, varscan2
- ARHGAP22 | c.1851C>G p.Y617* | Nonsense Mutation (SNP) | VAF 15/19 reads (79%) | catalogued as rs1333284391; called by muse, mutect2, varscan2
- ARHGEF3 | c.151C>G p.L51V | Missense Mutation (SNP) | VAF 33/44 reads (75%) | SIFT tolerated (0.1); PolyPhen benign (0.17); catalogued as COSV56325129; called by muse, mutect2, varscan2
- BSN | c.3733G>A p.A1245T | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs142148405; called by muse, mutect2, varscan2
- C12orf42 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT tolerated (0.82); PolyPhen benign (0.013); catalogued as COSV59380888; called by muse, mutect2, varscan2
- CDH10 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 63/174 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as rs749846087, COSV52576149; called by muse, mutect2, varscan2
- COL22A1 | c.4601C>T p.P1534L | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV57330677; called by muse, mutect2, varscan2
- CST6 | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV56409703; called by muse, mutect2, varscan2
- DIAPH2 | c.2298G>C p.E766D | Missense Mutation (SNP) | VAF 25/29 reads (86%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV61264671; called by muse, mutect2, varscan2
- DOC2A | c.1097G>T p.R366L | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58750952; called by muse, mutect2, varscan2
- EPHA2 | c.104del p.A35Vfs*20 | Frame Shift Del (DEL) | VAF 51/91 reads (56%) | catalogued as COSV64452571; called by mutect2, pindel*, varscan2
- FLACC1 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs143899839; called by muse, mutect2, varscan2
- HAS2 | c.1653T>A p.D551E | Missense Mutation (SNP) | VAF 57/201 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as COSV58262963; called by muse, mutect2, varscan2
- HTR1A | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1008675652, COSV60500343; called by muse, mutect2, varscan2
- LCA5 | c.1469C>T p.P490L | Missense Mutation (SNP) | VAF 71/188 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs139048294; called by muse, mutect2, varscan2
- LEPR | c.1883C>A p.P628Q | Missense Mutation (SNP) | VAF 62/137 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV60750839; called by muse, mutect2, varscan2
- MAGEA12 | c.750G>C p.L250F | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs1556833591, COSV63294511; called by muse, mutect2, varscan2
- MVP | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV62421711; called by muse, mutect2, varscan2
- NCF2 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 99/233 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs201869337; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEO1 | c.4207G>A p.G1403R | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs977602517, COSV99981049; called by muse, mutect2
- NFIL3 | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 64/168 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52683429; called by muse, mutect2, varscan2
- PCDH15 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 63/84 reads (75%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.986); catalogued as rs562377533, COSV57285343; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCOLCE2 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55998262; called by muse, mutect2, varscan2
- RHPN2 | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); catalogued as rs773144206, COSV54276890; called by muse, mutect2, varscan2
- RYR1 | c.11548A>C p.N3850H | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV62093575; called by muse, mutect2, varscan2
- SGK2 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755045211, COSV58312617; called by muse, mutect2, varscan2
- SKIL | c.1181C>G p.S394* | Nonsense Mutation (SNP) | VAF 34/94 reads (36%) | catalogued as rs140174204; called by muse, mutect2, varscan2
- SOS1 | c.1236G>A p.M412I | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV67674570; called by muse, mutect2, varscan2
- SVEP1 | c.6132C>G p.F2044L | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0.034); catalogued as COSV52837680; called by muse, mutect2, varscan2
- SZT2 | c.3902A>G p.Q1301R (on ENST00000634258 / NM_001365999.1; = p.Q1244R on NM_015284.4) | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (0.78); PolyPhen benign (0.236); catalogued as COSV65168518; called by muse, mutect2, varscan2
- TENM4 | c.2926C>T p.R976W | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53619075; called by muse, mutect2, varscan2
- TNKS | c.1945G>A p.D649N | Missense Mutation (SNP) | VAF 77/206 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.597); catalogued as COSV60054624; called by muse, mutect2, varscan2
- TRIM2 | c.1322C>T p.P441L (on ENST00000437508; = p.P468L on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV58632316; called by muse, mutect2, varscan2
- TTC27 | c.1820G>T p.R607L | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs776673745, COSV100512789, COSV58650314; called by muse, mutect2, varscan2
- UNC5D | c.2105A>G p.N702S | Missense Mutation (SNP) | VAF 72/197 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.013); catalogued as COSV54781991; called by muse, mutect2, varscan2
- USP13 | c.1661T>C p.V554A | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV55864158; called by muse, mutect2, varscan2
- YWHAE | c.148A>T p.K50* | Nonsense Mutation (SNP) | VAF 8/165 reads (5%) | catalogued as COSV99981309; called by muse, mutect2
- YWHAE | c.147T>A p.Y49* | Nonsense Mutation (SNP) | VAF 8/167 reads (5%) | catalogued as COSV99981313; called by muse, mutect2
- ZNF710 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 74/112 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs377693133; called by muse, mutect2, varscan2
- CACNA1A | c.2759G>A p.W920* | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | called by muse, mutect2, varscan2
- HES1 | c.108+2_108+48del p.X36_splice | Splice Site (DEL) | VAF 18/30 reads (60%) | called by mutect2, pindel
- KMT2D | c.14743_14759del p.S4915Lfs*11 | Frame Shift Del (DEL) | VAF 65/104 reads (63%) | called by mutect2, pindel, varscan2
- TMCO3 | c.1894C>T p.R632* | Nonsense Mutation (SNP) | VAF 49/133 reads (37%) | called by muse, mutect2, varscan2
- ZMYM3 | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 34/42 reads (81%) | called by muse, mutect2, varscan2
- ARFRP1 | c.60C>T p.I20= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as rs1340331586, COSV60831643; called by muse, mutect2, varscan2
- CIITA | c.2409G>A p.A803= | Silent (SNP) | VAF 34/58 reads (59%) | catalogued as rs755302593, COSV60855580; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNMD | c.189C>T p.Y63= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV65032752; called by muse, mutect2, varscan2
- EPN1 | c.519G>A p.A173= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs1486148960, COSV50036358; called by muse, mutect2, varscan2
- FRMD1 | c.405C>T p.A135= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as rs1417653155, COSV51961076; called by muse, mutect2, varscan2
- GMIP | c.1695C>T p.P565= | Silent (SNP) | VAF 37/120 reads (31%) | catalogued as COSV52555269; called by muse, mutect2, varscan2
- HYDIN | c.13911C>T p.F4637= | Silent (SNP) | VAF 18/59 reads (31%) | called by muse, mutect2, varscan2
- IGSF9 | c.2742C>T p.P914= (on ENST00000368094 / NM_001135050.2; = p.P898= on NM_020789.4) | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs1392394888; called by muse, mutect2, varscan2
- ITGAD | c.2067C>T p.F689= | Silent (SNP) | VAF 177/491 reads (36%) | catalogued as COSV66757399, COSV66757939; called by muse, mutect2, varscan2
- KANK4 | c.444C>T p.A148= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as rs567649436, COSV62986065, COSV62986958; called by muse, mutect2, varscan2
- KIF26B | c.1101G>T p.S367= | Silent (SNP) | VAF 35/133 reads (26%) | catalogued as COSV69458692; called by muse, mutect2, varscan2
- MAGT1 | c.495G>A p.Q165= (on ENST00000618282 / NM_001367916.1; = p.Q197= on NM_032121.5) | Silent (SNP) | VAF 78/100 reads (78%) | catalogued as COSV63781221; called by muse, mutect2, varscan2
- MYBPC2 | c.336C>T p.S112= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs1282693168, COSV63094382; called by muse, varscan2
- NWD1 | c.1410G>A p.S470= | Silent (SNP) | VAF 56/167 reads (34%) | catalogued as rs749508047, COSV60340158; called by muse, mutect2, varscan2
- OR51A2 | c.453C>A p.S151= | Silent (SNP) | VAF 38/141 reads (27%) | catalogued as COSV66748231; called by muse, mutect2, varscan2
- PAK3 | c.1431C>T p.Y477= (on ENST00000262836 / NM_001324328.2; = p.Y462= on NM_002578.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV53272611; called by muse, mutect2, varscan2
- PXDNL | c.2814A>G p.T938= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV62484181; called by muse, mutect2, varscan2
- RNPS1 | c.870G>A p.P290= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs1294748521, COSV57042779; called by muse, mutect2, varscan2
- SLC5A11 | c.675G>A p.A225= | Silent (SNP) | VAF 105/278 reads (38%) | catalogued as rs756403795, COSV61740895; called by muse, mutect2, varscan2
- SUPT16H | c.1890A>G p.K630= | Silent (SNP) | VAF 20/137 reads (15%) | catalogued as rs1222189597, COSV53523413; called by muse, mutect2, varscan2
- TMEM63A | c.1437C>T p.L479= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as rs377208935, COSV64762780; called by muse, mutect2, varscan2
- KCNAB1 | c.275+22361A>T | Intron (SNP) | VAF 26/61 reads (43%) | catalogued as COSV67485061; called by muse, mutect2, varscan2
- RNF217-AS1 | n.3229A>C | RNA (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
